Gene-level copy-number profile of tumor specimen ALCH-B35B-TTP1-A from ALCHEMIST case ALCH-B35B, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 52.5 years (19,163 days).
Specimen ALCH-B35B-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6f6b34c1-a3b6-432d-9cd5-40563f4eb7ba.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B35B-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/a36fa6ed-6e90-47d6-86d7-bf1eeac4cd4a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 29; copy number 1: 8,050; copy number 2: 44,989; copy number 3: 5,494; copy number 4: 2; copy number 5: 17; copy number 6: 35; copy number 7: 34; copy number 8: 67; copy number 9: 116; copy number 10: 60; copy number 11: 5; copy number 12: 5.

Homozygous deletions (total copy number 0; autosomes only): 26 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:8,592,660–8,619,759, 1 gene (within-gene range 0–2): CPZ.
- chr9:133,611,798–133,659,329, 3 genes: AC002101.1, DBH, DBH-AS1.
- chr15:25,176,832–25,211,877, 20 genes (within-gene range 0–2): SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23.
- chr17:17,476,994–17,496,395, 2 genes: MED9, RASD1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 339 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:946,315–13,250,662, 207 genes, copy number 5–11 (broad region; genes not listed).
- chr5:13,690,331–17,615,111, 76 genes, copy number 6–12 (broad region; genes not listed).
- chr5:17,647,712–23,014,527, 41 genes, copy number 7–8: AC233724.1, AC233724.5, AC233724.2, H3Y1, AC233724.8, H3P22, LINC02223, RPL36AP21, SNORD81, RN7SL58P, LINC02100, UBE2V1P12, AC025768.1, AC114981.1, Metazoa_SRP, AC106744.1, AC106744.2, RPL32P14, HSPD1P15, CDH18, AC093303.1, AC094103.1, CDH18-AS1, LINC02146, LINC02241, AC138938.1, AC140172.1, AC093274.1, GUSBP1, AC138951.1, AC138951.2, AC091946.2, AC091946.1, CDH12, HSPD1P1, AC139497.1, PMCHL1, AC138854.1, GCNT1P2, AC091938.1, AC010445.1.
- chr5:24,749,374–25,445,925, 15 genes, copy number 5: AC091893.1, AC106821.2, BTG4P1, SNORD29, LINC02239, AC106821.1, Y_RNA, LINC02228, LINC02211, AC099499.2, AC099499.1, AC106754.1, AC106754.2, AC022140.1, AC022140.2.

Autosomal genes at a single copy (total copy number 1): 5,201. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
